Gene-level copy-number profile of tumor specimen TCGA-77-A5G8-01B from TCGA case TCGA-77-A5G8, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.0 years (25,921 days).
Specimen TCGA-77-A5G8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.96b23cfd-5f3f-4832-a1a6-feee12ffd53d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-A5G8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64669a68-0076-4f95-8c36-2d35f2014202

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 610; copy number 2: 30,908; copy number 3: 14,951; copy number 4: 4,446; copy number 5: 5,823; copy number 6: 1,442; copy number 7: 1,027; copy number 8: 404; copy number 9: 194; copy number 11: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-A5G8-01B-11D-A27J-01): tumor purity 0.44, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,897 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–214,664,571, 1,854 genes, copy number 5 (broad region; genes not listed).
- chr1:235,661,041–238,538,305, 49 genes, copy number 5–11: LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, AL122018.2, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32.
- chr3:93,843,764–97,752,460, 29 genes, copy number 5 (within-gene range 4–5): RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1.
- chr3:122,411,846–126,960,420, 107 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:137,518,134–198,222,513, 1,064 genes, copy number 5–8 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr7:70,972–119,179,149, 2,160 genes, copy number 5–7 (broad region; genes not listed).
- chr8:34,784,028–35,796,550, 6 genes, copy number 7 (within-gene range 4–7): LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1.
- chr10:4,987,400–53,766,614, 857 genes, copy number 5 (broad region; genes not listed).
- chr19:29,213,235–40,414,793, 444 genes, copy number 7–9 (broad region; genes not listed).
- chr20:87,250–36,088,192, 766 genes, copy number 5 (broad region; genes not listed).
- chr22:15,290,718–34,218,796, 851 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 610. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
